Somatic mutation profile of tumor specimen 0DQB2V from CCDI case PBCESI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.5 years (917 days).
Specimen 0DQB2V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a923e651-8914-4ebf-947e-f7d805e8a0ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB23 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5440e8e-507e-4000-b589-70e811f40e2f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD3B1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 32/900 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2
- POLE | c.3661C>A p.P1221T | Missense Mutation (SNP) | VAF 24/868 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- GGTLC1 | c.102C>T p.D34= | Silent (SNP) | VAF 232/602 reads (39%) | catalogued as rs146964922; called by muse, varscan2
